Surgical pathology report (de-identified scan), TCGA case TCGA-KM-A7QL, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-A7QL-01C (Primary Tumor).

[page 1 of 2]
Gender: Female	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology [OrderID:	Final Results
------------------------------	---------------

Surgical Pathology
CASE NUMBER:
DIAGNOSIS:

Final

1. Kidney, left, tumor #1, excision: Renal parenchyma, no tumor seen.
2. Kidney, left, tumor #2, excision: Renal cell carcinoma, chromophobe type.
3. Kidney, left tumor #2, deep margin, excision: Fibrofatty tissue, no tumor seen.
4. Perirenal fat, left, "fat over largest tumor outer margin", excision: Fatty fibroadipose tissue, no tumor seen.

ICD-O-3
Carcinoma, renal cell
Chromophobe type 8317/3
Site C Kidney NOS C64.9
JW 9/24/13

CLINICAL INFORMATION: Allocate Order to Protocol: Brief
Clinical History: Birt
Hogg Dube Specimen Taken For Protocol:

PROCEDURE: Pre-Operative Diagnosis: Birt Hogg Dube, Left renal mass
Post-Operative Diagnosis: same Operative Findings: left renal mass

- SPECIMENS SUBMITTED: 1. TUMOR, Left kidney # 1
2. TUMOR, Left kidney # 2
3. TUMOR, Left kidney deep margin # 2
4. FAT, Over largest tumor outer margin

GROSS DESCRIPTION: Received are 4 freshly submitted tissues in containers labeled with the patient's name, medical record number, and further described as follows:

1. "LT kidney tumor #1". One specimen is received in with the patient's name, medical record number, and labeled "left kidney tumor #1". It consists of multiple tan to dark red soft tissue fragments measuring in aggregate 2 x 1.2 x 0.3 cm. It is filtered and entirely submitted in a white cassette labeled
2. "Left kidney tumor #2". The specimen consists of a tan-pink nodule partially covered by normal-appearing kidney parenchyma, overall 3 x 2.5 x 2.2 cm. The nodule itself is 1.5 x 1 x 1 cm. It has a tan fleshy, bulging cut surface with minimal punctate hemorrhage. Gross photographs are taken. Approximately half of the specimen is procured for
Following the procurement, per request, the deep margin is inked black and the remaining peripheral margin is inked blue. The specimen is subsequently placed into formalin and submitted to Pathology for permanent. The specimen is received in Pathology and matches the above

[page 2 of 2]
Gender: Female	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology [OrderID:Final Results

description. The specimen is serially sectioned and submitted in white cassettes labeled #2A-2D.

3. "Tumor #2 deep margin". A third specimen is received in formalin with the patient's name, medical record number, and labeled "tumor #2 deep margin". It consists of a single white soft tissue fragment measuring 0.2 x 0.2 cm. It is filtered and entirely submitted in a white cassette labeled #3.

4. "Fat over largest tumor outer margin". A fourth specimen is received in formalin with the patient's name, medical record number, and labeled "fat over largest tumor outer margin". It consists of multiple yellow and tan-pink soft tissue fragments measuring in aggregate 7.5 x 4 x 1 cm. Representative sections demonstrating the relationship of the adipose tissue to the kidney capsule are submitted in white cassettes labeled #4A-4C.

Gross description dictated by
gross description dictated by

Additional

No consultants
Accessioned:
Final Report Signed Out:

Date Report Signed:

Source: NCI Genomic Data Commons file b0bcfdcf-9acd-4946-8e16-00e5d0483bda (TCGA-KM-A7QL.D6254CE0-CBFE-4FA2-BC0C-4A74D02E556F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).